Somatic mutation profile of tumor specimen TARGET-10-PATALJ-09A (aliquot TARGET-10-PATALJ-09A-01D) from TARGET case TARGET-10-PATALJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.8 years (4,669 days).
Specimen TARGET-10-PATALJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 912254af-0f18-4958-b3af-2f1b72a3ade4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATALJ-10A (Blood Derived Normal), aliquot TARGET-10-PATALJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a10259f2-82e0-4192-9c44-6c4804d2598b

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 5, Silent 5, Frame Shift Ins 4, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs398123999, CM010809, COSV55895968, COSV99053163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 44/50 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, varscan2
- ATP2B2 | c.2120G>A p.R707H (on ENST00000352432; = p.R673H on NM_001683.5) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs928659205, COSV59505783; called by muse, mutect2, varscan2
- ATP8B3 | c.3302G>T p.S1101I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as COSV59547543; called by muse, mutect2, varscan2
- CAPZA3 | c.671G>C p.S224T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV56857738; called by muse, mutect2, varscan2
- CHSY3 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59285928; called by muse, mutect2, varscan2
- FAT1 | c.11128C>T p.Q3710* | Nonsense Mutation (SNP) | VAF 47/58 reads (81%) | catalogued as COSV71674289; called by muse, mutect2, varscan2
- FGG | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60196549; called by muse, mutect2, varscan2
- GNB2 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51946057; called by muse, mutect2, varscan2
- GPRC6A | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59955450; called by muse, mutect2, varscan2
- IRGC | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs762043191, COSV54984460, COSV99746397; called by muse, varscan2
- KCNA4 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.04); catalogued as rs769344328, COSV60250408; called by muse, mutect2, varscan2
- NALCN | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs956246464, COSV51959578; called by muse, mutect2, varscan2
- NLRP4 | c.2897C>A p.T966N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56721485; called by muse, mutect2, varscan2
- OPCML | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762120321, COSV59404700; called by muse, mutect2, varscan2
- OR5M8 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs751479435, COSV59117948; called by muse, mutect2, varscan2
- PLEKHG3 | c.3318C>A p.S1106R (on ENST00000394691; = p.S1162R on NM_001308147.2) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55983036; called by muse, mutect2, varscan2
- RABGAP1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs747224854, COSV65395427; called by mutect2, varscan2
- ROBO1 | c.4600G>T p.V1534L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs748995062, COSV71397794; called by muse, varscan2
- TLE6 | c.842G>A p.R281Q (on ENST00000246112 / NM_001143986.2; = p.R158Q on NM_024760.3) | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as rs376615116; called by muse, mutect2, varscan2
- TSNAX | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64147084; called by muse, mutect2, varscan2
- ZNF532 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs761715303, COSV60171940; called by muse, mutect2, varscan2
- ZSWIM5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs765190893, COSV62736327; called by muse, mutect2, varscan2
- ARFGEF3 | c.4856_4857insGAAG p.P1621Qfs*65 | Frame Shift Ins (INS) | VAF 7/16 reads (44%) | called by muse*, mutect2
- NCOA2 | c.552dup p.S185Ifs*25 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- NOS3 | c.1999_2006del p.V667Tfs*39 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- PHF6 | c.310_311insCCCCACC p.H104Pfs*10 | Frame Shift Ins (INS) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- PHF6 | c.502A>T p.R168* (on ENST00000332070 / NM_032458.3; = p.R169* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- PIAS1 | c.413_414dup p.Q139Ffs*13 | Frame Shift Ins (INS) | VAF 26/44 reads (59%) | called by mutect2, pindel, varscan2
- RNPS1 | c.819-2A>C p.X273_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- AAAS | c.1155A>C p.T385= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- DOCK4 | c.4062C>T p.N1354= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs368980000; called by muse, mutect2, varscan2
- EXOC3L2 | c.1254C>T p.C418= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs757415310; called by muse, mutect2, varscan2
- NOL8 | c.105G>A p.S35= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs772226439; called by muse, mutect2, varscan2
- SLC16A13 | c.789C>T p.L263= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- FBXO32 | c.466+31T>A | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- FRG1GP | n.761G>T | RNA (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- RORC | c.934-30C>T | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- RTP1 | c.273-35G>A | Intron (SNP) | VAF 18/49 reads (37%) | catalogued as rs569450047; called by muse, mutect2, varscan2
- SIVA1 | c.471-229G>C | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- SLCO1A2 | c.61-515C>A | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
